Somatic mutation profile of tumor specimen MMRF_2238_1_BM_CD138pos (aliquot MMRF_2238_1_BM_CD138pos_T1_KHS5U_L09533) from MMRF case MMRF_2238, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 52.7 years (19,246 days).
Specimen MMRF_2238_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9925b167-8225-4448-831a-cbc54de56c8f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2238_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2238_1_PB_Whole_C3_KHS5U_L09534; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3c2fc8ed-86de-4b92-8b48-d825a3d4891f

The open-access MAF lists 75 somatic variants for this specimen: 27 protein-altering or splice-affecting, 9 silent, 39 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 25, Missense Mutation 24, Silent 9, 5'UTR 5, Intron 5, Nonsense Mutation 2, RNA 2, 5'Flank 1, 3'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.404G>A p.C135Y | Missense Mutation (SNP) | VAF 48/55 reads (87%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587781991, COSV52675774, COSV52680475, COSV52702460, COSV53452020; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- EML2 | c.1436C>T p.S479F | Missense Mutation (SNP) | VAF 33/130 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1466778775, COSV55600294; called by muse, varscan2
- IGHV2-70D | c.261G>T p.R87S | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.068); catalogued as rs1415610196; called by muse, varscan2
- IGLV3-1 | c.71C>T p.T24I | Missense Mutation (SNP) | VAF 48/100 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.5); catalogued as rs186574328; called by muse, varscan2
- MPPED1 | c.733C>T p.H245Y | Missense Mutation (SNP) | VAF 55/119 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs889365337; called by muse, mutect2, varscan2
- MYO7A | c.4694C>T p.T1565M | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs764915160; called by muse, mutect2, varscan2
- RPL11 | c.43C>A p.R15S (on ENST00000374550 / NM_001199802.1; = p.R16S on NM_000975.5) | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.073); catalogued as COSV104424061, COSV65778940; called by muse, mutect2, varscan2
- RTL8C | c.284G>A p.R95Q | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV99924364; called by muse, mutect2, varscan2
- SEMA4D | c.2120C>T p.S707F | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.523); catalogued as COSV59399294; called by muse, mutect2, varscan2
- SLC6A3 | c.399G>C p.K133N | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as CD108195, COSV99548205; called by muse, mutect2, varscan2
- ACTG1 | c.139A>G p.M47V | Missense Mutation (SNP) | VAF 101/226 reads (45%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); called by muse, varscan2
- ADGRD1 | c.2119T>A p.S707T | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- DNHD1 | c.4984C>T p.P1662S | Missense Mutation (SNP) | VAF 72/219 reads (33%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- FLG2 | c.5600A>T p.Q1867L | Missense Mutation (SNP) | VAF 64/204 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- FOLH1 | c.694G>A p.A232T | Missense Mutation (SNP) | VAF 16/16 reads (100%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.502); called by mutect2, varscan2
- H1-4 | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 45/105 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- HERC1 | c.14221G>A p.V4741M | Missense Mutation (SNP) | VAF 229/340 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- IGHV2-70 | c.123_157delinsACCTTCTCTGGATTCTCACTCAACACTAGTCTAG p.C41* | Nonsense Mutation (DEL) | VAF 10/66 reads (15%) | called by muse*, pindel, varscan2*
- IGHV2-70D | c.142C>G p.L48V | Missense Mutation (SNP) | VAF 42/76 reads (55%) | SIFT tolerated (0.13); PolyPhen benign (0.023); called by muse, varscan2
- IGHV5-51 | c.349A>G p.R117G | Missense Mutation (SNP) | VAF 32/61 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.416); called by muse, mutect2, varscan2
- IYD | c.271C>T p.Q91* | Nonsense Mutation (SNP) | VAF 90/176 reads (51%) | called by muse, varscan2
- KCNF1 | c.303G>T p.K101N | Missense Mutation (SNP) | VAF 52/117 reads (44%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- MAGEC2 | c.842del p.G281Dfs*35 | Frame Shift Del (DEL) | VAF 52/70 reads (74%) | called by mutect2, pindel, varscan2
- NFYC | c.1336C>A p.Q446K (on ENST00000308733 / NM_001308114.1; = p.Q323K on NM_014223.5) | Missense Mutation (SNP) | VAF 125/235 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- NPAS4 | c.1982C>G p.P661R | Missense Mutation (SNP) | VAF 59/122 reads (48%) | SIFT tolerated (0.26); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- TARBP1 | c.1280C>T p.S427L | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- ZNF561 | c.445A>G p.N149D | Missense Mutation (SNP) | VAF 261/588 reads (44%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- CYP4A22 | c.1137A>G p.A379= | Silent (SNP) | VAF 70/77 reads (91%) | catalogued as COSV99595161; called by muse, mutect2, varscan2
- GON4L | c.4908C>T p.T1636= | Silent (SNP) | VAF 86/251 reads (34%) | called by muse, mutect2, varscan2
- GRAMD1A | c.237C>T p.Y79= | Silent (SNP) | VAF 12/68 reads (18%) | called by muse, varscan2
- GRAMD1A | c.291C>T p.F97= | Silent (SNP) | VAF 34/186 reads (18%) | called by muse, varscan2
- IGHV1-69D | c.303G>A p.E101= | Silent (SNP) | VAF 75/137 reads (55%) | called by muse, mutect2, varscan2
- IGHV2-70 | c.333A>C p.T111= | Silent (SNP) | VAF 28/54 reads (52%) | catalogued as rs367992030; called by muse, varscan2
- IGHV2-70D | c.231T>C p.D77= | Silent (SNP) | VAF 39/85 reads (46%) | called by muse, varscan2
- WASHC5 | c.3144C>T p.I1048= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as rs367647052; called by muse, mutect2
- ZNF536 | c.2025C>A p.G675= | Silent (SNP) | VAF 60/89 reads (67%) | catalogued as COSV62823282; called by muse, mutect2, varscan2
- AC012560.1 | n.371C>T | RNA (SNP) | VAF 25/57 reads (44%) | called by muse, mutect2, varscan2
- ARHGEF12 | c.3278-86G>C | Intron (SNP) | VAF 31/72 reads (43%) | called by muse, mutect2, varscan2
- ARRDC2 | c.489+47G>C | Intron (SNP) | VAF 52/76 reads (68%) | called by muse, mutect2, varscan2
- BLOC1S6 | c.*2171_*2174del | 3'UTR (DEL) | VAF 23/78 reads (29%) | called by mutect2, pindel, varscan2
- BRWD1 | c.6571+2887C>A | Intron (SNP) | VAF 26/100 reads (26%) | called by muse, mutect2, varscan2
- BTBD1 | c.*474A>G | 3'UTR (SNP) | VAF 17/169 reads (10%) | called by muse, mutect2
- C11orf68 | c.-17G>A | 5'UTR (SNP) | VAF 87/166 reads (52%) | called by muse, mutect2, varscan2
- CAPRIN1 | c.*1242C>G | 3'UTR (SNP) | VAF 27/58 reads (47%) | called by muse, mutect2, varscan2
- CDH19 | c.*3024G>A | 3'UTR (SNP) | VAF 17/43 reads (40%) | called by muse, mutect2, varscan2
- CDH7 | chr18:65882264 G>A | 3'Flank (SNP) | VAF 38/89 reads (43%) | catalogued as COSV59881663; called by muse, mutect2, varscan2
- CMTM5 | c.*105C>T | 3'UTR (SNP) | VAF 7/14 reads (50%) | called by muse, mutect2
- CYYR1 | c.-192G>A | 5'UTR (SNP) | VAF 17/41 reads (41%) | catalogued as rs906810433; called by muse, mutect2, varscan2
- DNM1L | c.-2T>C | 5'UTR (SNP) | VAF 35/74 reads (47%) | called by muse, mutect2, varscan2
- ELOVL5 | c.*953A>G | 3'UTR (SNP) | VAF 40/70 reads (57%) | catalogued as rs1283962163; called by muse, mutect2, varscan2
- FGFR3 | c.*227_*250del | 3'UTR (DEL) | VAF 28/78 reads (36%) | called by mutect2, varscan2
- GBP6 | c.*893dup | 3'UTR (INS) | VAF 14/80 reads (18%) | called by mutect2, pindel, varscan2
- GDF3 | c.*17A>C | 3'UTR (SNP) | VAF 212/452 reads (47%) | called by muse, mutect2, varscan2
- GOLPH3 | c.*888C>T | 3'UTR (SNP) | VAF 26/57 reads (46%) | called by muse, mutect2, varscan2
- GRK6 | c.*984G>C | 3'UTR (SNP) | VAF 36/73 reads (49%) | called by muse, mutect2, varscan2
- IGKV6D-21 | c.-21C>T | 5'UTR (SNP) | VAF 58/124 reads (47%) | catalogued as rs763758804; called by muse, varscan2
- LPP | c.*4822T>G | 3'UTR (SNP) | VAF 38/72 reads (53%) | called by muse, mutect2, varscan2
- METTL9 | c.*1463T>C | 3'UTR (SNP) | VAF 28/67 reads (42%) | called by muse, mutect2, varscan2
- MFAP3L | c.*2549G>A | 3'UTR (SNP) | VAF 14/36 reads (39%) | called by muse, mutect2, varscan2
- NANP | c.*1227C>T | 3'UTR (SNP) | VAF 22/40 reads (55%) | called by muse, mutect2, varscan2
- NCAM2 | c.*1737T>G | 3'UTR (SNP) | VAF 20/83 reads (24%) | called by muse, mutect2
- NDUFV2P1 | n.29G>A | RNA (SNP) | VAF 30/52 reads (58%) | called by muse, mutect2, varscan2
- RPL37 | c.*619G>A | 3'UTR (SNP) | VAF 42/94 reads (45%) | called by muse, mutect2, varscan2
- RPRD1B | c.*1511A>T | 3'UTR (SNP) | VAF 16/34 reads (47%) | called by muse, mutect2, varscan2
- RPRD1B | c.*1686A>T | 3'UTR (SNP) | VAF 35/67 reads (52%) | called by muse, mutect2, varscan2
- SIDT1 | c.1046-26G>A | Intron (SNP) | VAF 58/123 reads (47%) | called by muse, mutect2, varscan2
- SLC32A1 | c.-73G>A | 5'UTR (SNP) | VAF 18/50 reads (36%) | called by muse, mutect2, varscan2
- SMPDL3B | c.*89G>T | 3'UTR (SNP) | VAF 27/90 reads (30%) | called by muse, mutect2, varscan2
- STMN3 | c.*215dup | 3'UTR (INS) | VAF 8/25 reads (32%) | called by mutect2, pindel, varscan2
- TAF3 | c.*1306T>C | 3'UTR (SNP) | VAF 24/51 reads (47%) | called by muse, mutect2, varscan2
- TRAM1L1 | c.*228A>C | 3'UTR (SNP) | VAF 28/60 reads (47%) | called by muse, mutect2, varscan2
- TRARG1 | c.*1751G>A | 3'UTR (SNP) | VAF 32/33 reads (97%) | catalogued as rs1028523294; called by muse, mutect2, varscan2
- ZFAND2A | c.150+182T>A | Intron (SNP) | VAF 14/24 reads (58%) | called by muse, mutect2, varscan2
- ZNF460 | c.*31C>A | 3'UTR (SNP) | VAF 56/132 reads (42%) | called by muse, mutect2, varscan2
- ZNF774 | chr15:90349133 C>T | 5'Flank (SNP) | VAF 77/236 reads (33%) | catalogued as rs1246126331; called by muse, mutect2, varscan2
